TCGA case TCGA-UY-A8OD — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: University of California San Francisco. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fa2410b1-4f69-446d-99ee-a10a00034c42

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 67.3 years (24,588 days); Method of diagnosis: Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 3,432 days (9.4 years).
   Pathology details: Consistent pathology review: Yes.

Follow-up (1 entry)
- Days to follow up: 3,432 days (9.4 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-UY-A8OD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 40 mg.
  Slide TCGA-UY-A8OD-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-UY-A8OD-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-UY-A8OD-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Bladder - NOS; Method initial path diagnosis: Endoscopic Biopsy; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,432 days; disease-specific survival: no event (censored), 3,432 days; disease-free interval: no event (censored), 3,432 days; progression-free interval: no event (censored), 3,432 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-UY-A8OD-01A-11D-A363-01): tumor purity 0.54, ploidy 3.76, whole-genome doublings 1.
